Somatic mutation profile of tumor specimen TCGA-13-0768-01A (aliquot TCGA-13-0768-01A-01W-0371-08) from TCGA case TCGA-13-0768, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.9 years (26,999 days).
Specimen TCGA-13-0768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc01e12c-7047-4495-8cee-330dbd85a058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0768-10A (Blood Derived Normal), aliquot TCGA-13-0768-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5882c8f-6432-46f0-9c41-80f9699f60a4

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 142/601 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COCH | c.697T>G p.F233V (on ENST00000216361 / NM_001347720.1; = p.F168V on NM_004086.3) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV99363850; called by muse, varscan2
- FGF6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs892861468, COSV57403250; called by muse, varscan2
- FPGT-TNNI3K | c.1506G>A p.W502* | Nonsense Mutation (SNP) | VAF 97/577 reads (17%) | catalogued as COSV100437522; called by muse, mutect2, varscan2
- GNAS | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs747496009, COSV99670729; called by muse, mutect2, varscan2
- KMT2C | c.7810C>A p.H2604N | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100074958; called by muse, mutect2
- TTBK2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 81/814 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780766324, COSV99142206; called by mutect2, varscan2
- ZNF608 | c.3808A>G p.S1270G | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as rs1249224285, COSV100102237; called by muse, varscan2
- DNM3 | c.211C>T p.L71= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as COSV100798523; called by muse, mutect2, varscan2
- RAB6C | c.732C>T p.C244= | Silent (SNP) | VAF 24/320 reads (8%) | catalogued as COSV101308537; called by muse, mutect2
- ZNF646 | c.1413T>C p.G471= | Silent (SNP) | VAF 680/696 reads (98%) | catalogued as COSV56211468; called by muse, varscan2
